Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7616, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7616-01A (Primary Tumor).

Pathology Report for Subject: [REDACTED]

Addendum Discussion: The neoplastic cells exhibit cytoplasmic immunoreactivity for GFAP. The background brain parenchyma demonstrates immunopositivity for synaptophysin. CAM 5.2 is essentially negative. The MIB-1 labeling index ranges up to 6.5% in the most proliferative regions of tumor. Overall, the histologic features are consistent with an anaplastic oligodendroglioma.

Addendum Diagnosis:

1-3. Anaplastic Oligodendroglioma.
- MIB-1 labeling index = 6.5%.

Microscopic Description:

1. Permanent section of the frozen section specimen demonstrates hypercellular brain with numerous scattered macrophages, many of which contain hemosiderin. There are admixed reactive small cells as well as clusters of cells that may represent neoplasm.

2,3. Sections demonstrate sheets and irregular large nodules of neoplastic cells associated with extensive necrosis. In some areas a myxoid stroma is seen. Blood vessels are thick walled and hypercellular and, in specimen 2, hyalinized. Atypia is moderate and mitotic figures are surprisingly rare. In the unfrozen material the tumor cells tend to have small to intermediate sized round nuclei with a small nucleolus. The cytoplasm is clear. Although much of the tumor is a nodular pattern, slide 3A shows apparent diffuse infiltration.

Source: NCI Genomic Data Commons file e1a98e08-5edd-4a3d-a11c-4cc348b39390 (TCGA-HT-7616.D8E58500-52B1-4FAD-8A36-7DDEC42B5632.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).